Surgical pathology report (de-identified scan), TCGA case TCGA-DY-A1DE, project TCGA-READ (Rectum Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DY-A1DE-01A (Primary Tumor).

Adenocarcinoma, NOS 8140/3
Site Code: Rectum, NOS C20.9

1/10/11
JW

(First Tumor)

Tumor Site:	Rectum		
Date of Cancer Sample Procurement:			
Histology:	Adenocarcinoma		
Description of other histology:			
Grade:	Moderately Differentiated		
Mucinous:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No	☐ Yes	☐ Unknown
Host Response:	Lymphoid Aggregates		
Crohn's like reaction	☐ None	☒ Yes	☐ Unknown
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown
Growth Pattern:	☒ Expansile	☐ Invasive	☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No	☐ Yes	☐ Unknown
Angiolymphatic Invasion:	☒ No	☐ Yes	☐ Unknown
Mutator Phenotype:	☒ No	☐ Yes	☐ Unknown
Number of Slides	1		
Garland Necrosis present:	☐ No	☒ Yes	☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	8		
Pathologist Comment:			

HIFAA Discrepancy		☒

Source: NCI Genomic Data Commons file c932b714-465f-4135-9b98-c7b0f0d86361 (TCGA-DY-A1DE.44B82141-2558-4805-8B58-B2E502768527.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).